Somatic mutation profile of tumor specimen BA2668D (aliquot aq-BA2668D) from BEATAML1.0 case 2226, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.2 years (27,115 days).
Specimen BA2668D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b81c483-bfcf-4323-8a1f-ed3543c196a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2210D (Solid Tissue Normal), aliquot aq-BA2210D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ff41f6a-8ae5-4bd1-b713-6c8391eb3003

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO2 | c.2455G>T p.A819S (on ENST00000356134 / NM_001278597.3; = p.A823S on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.09); called by muse, mutect2
- MEF2C | c.990G>T p.L330= | Silent (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
